Gene-level copy-number profile of tumor specimen TCGA-B6-A0IN-01A from TCGA case TCGA-B6-A0IN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 45.7 years (16,705 days).
Specimen TCGA-B6-A0IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.83dfa7a2-901f-40ed-ab73-fa8f0a938566.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1c1ae48-6c74-458a-a038-9a672ab1aee7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,569; copy number 2: 42,367; copy number 3: 8,525; copy number 4: 779; copy number 5: 238; copy number 6: 392; copy number 7: 493; copy number 8: 129; copy number 9: 187; copy number 10: 12; copy number 11: 13; copy number 12: 44; copy number 17: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IN-01A-11D-A036-01): tumor purity 0.59, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,556 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,115,197–1,153,726, 1 gene, copy number 6 (within-gene range 3–6): TMED11P.
- chr4:1,151,372–2,043,970, 26 genes, copy number 6: AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48.
- chr6:43,370,026–46,606,162, 70 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:46,852,522–47,042,350, 3 genes, copy number 8 (within-gene range 3–8): ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:47,477,243–48,795,513, 17 genes, copy number 5–8: AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1.
- chr6:55,106,460–55,579,197, 3 genes, copy number 8 (within-gene range 2–8): HCRTR2, GFRAL, HMGCLL1.
- chr7:65,525,629–66,071,318, 17 genes, copy number 7: AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1.
- chr7:70,837,738–71,713,600, 5 genes, copy number 6: AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75.
- chr7:71,913,738–71,942,468, 2 genes, copy number 6: RNA5SP232, AC005011.1.
- chr7:78,017,055–79,453,667, 1 gene, copy number 6 (within-gene range 3–6): MAGI2.
- chr7:78,347,142–79,030,345, 6 genes, copy number 6: RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P.
- chr7:127,997,597–131,496,632, 126 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:135,246,113–136,084,668, 15 genes, copy number 6 (within-gene range 4–6): SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1.
- chr7:136,129,980–136,130,081, 1 gene, copy number 6: Y_RNA.
- chr7:140,084,746–151,076,526, 352 genes, copy number 6–8 (within-gene range 1–8) (broad region; genes not listed).
- chr7:155,962,632–159,233,377, 50 genes, copy number 5: AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr17:39,063,313–39,154,394, 1 gene, copy number 5 (within-gene range 3–5): PLXDC1.
- chr17:39,156,894–39,670,475, 19 genes, copy number 5: ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT.
- chr17:54,968,727–55,173,632, 1 gene, copy number 6: STXBP4.
- chr17:55,882,301–56,595,611, 5 genes, copy number 7 (within-gene range 2–7): ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:61,679,139–67,785,293, 182 genes, copy number 5–9 (broad region; genes not listed).
- chr19:39,812,972–40,465,764, 35 genes, copy number 6: AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP.
- chr19:41,442,102–42,220,140, 41 genes, copy number 6: Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL, RABAC1, AC010616.1, ATP1A3, GRIK5, ZNF574, POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2.
- chr19:46,297,042–46,828,440, 33 genes, copy number 7: HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A, PPP5D1, PNMA8B, AC011484.1, AC011551.1, GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1.
- chr19:48,170,680–48,630,717, 26 genes, copy number 7: ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1, GRIN2D, GRWD1, KCNJ14, AC008403.2, AC008403.1, CYTH2, LMTK3, AC008403.3, SULT2B1, FAM83E, SPACA4, RPL18, AC022154.1, SPHK2.
- chr19:49,255,472–50,466,321, 91 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:53,007,512–53,193,386, 8 genes, copy number 6: AC010328.1, ERVV-1, ERVV-2, ZNF160, ZNF415, ZNF347, ZNF665, AC092070.1.
- chr19:54,031,412–56,436,035, 189 genes, copy number 6–8 (broad region; genes not listed).
- chr21:22,882,582–28,674,848, 76 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr21:32,913,649–33,359,864, 14 genes, copy number 8: AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1.
- chr22:27,676,559–28,679,865, 13 genes, copy number 6–10 (within-gene range 2–10): AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2.
- chr22:28,303,754–28,742,422, 4 genes, copy number 6 (within-gene range 5–6): Y_RNA, MIR5739, RN7SL162P, CHEK2.
- chr22:34,756,676–35,347,992, 11 genes, copy number 12 (within-gene range 1–12): LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069.
- chr22:36,860,988–37,035,513, 9 genes, copy number 7 (within-gene range 2–7): NCF4, CSF2RB, CSF2RBP1, LL22NC01-81G9.3, TEX33, TST, Y_RNA, MPST, Z73420.1.
- chr22:47,115,838–50,801,309, 103 genes, copy number 5–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
